Gene-level copy-number profile of tumor specimen TCGA-AN-A0AM-01A from TCGA case TCGA-AN-A0AM, project TCGA-BRCA (Breast Invasive Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Breast, NOS; AJCC pathologic stage: Stage IIA; Age at diagnosis: 56.7 years (20,713 days).
Specimen TCGA-AN-A0AM-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-BRCA.e444884d-d4ee-4ffb-a429-558fd4c1dd5a.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-AN-A0AM-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 814 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; AscatNGS; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/3ca408e5-1e70-4817-92e1-088c30439877

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 2: 10,322; copy number 3: 21,278; copy number 4: 18,503; copy number 5: 3,360; copy number 6: 2,334; copy number 7: 850; copy number 8: 462; copy number 9: 991; copy number 10: 210; copy number 11: 97; copy number 12: 417; copy number 13: 218; copy number 14: 46; copy number 15: 29; copy number 16: 85; copy number 17: 69; copy number 18: 60; copy number 19: 108; copy number 20: 5; copy number 21: 49; copy number 22: 31; copy number 23: 37; copy number 24: 52; copy number 26: 1; copy number 29: 74; copy number 31: 2; copy number 33: 1; copy number 36: 7; copy number 39: 3; copy number 41: 12; copy number 42: 5; copy number 44: 14; copy number 46: 3; copy number 49: 5; copy number 50: 2; copy number 51: 60; copy number 69: 7.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-AN-A0AM-01A-11D-A036-01): tumor purity 0.34, ploidy 3.43, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 3,686 genes in 81 contiguous regions (the 40 largest listed; coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:51,354,263–56,996,757, 164 genes, copy number 8–13 (broad region; genes not listed).
- chr1:58,228,682–62,178,675, 43 genes, copy number 8–15 (within-gene range 6–15): AL357373.1, OMA1, AL035411.3, AL035411.2, RN7SL713P, TACSTD2, AL035411.1, MYSM1, AL136985.3, JUN, LINC01135, AL136985.2, AL136985.1, LINC02777, LINC01358, PHBP3, AL592431.2, AL592431.1, HSD52, AC093424.1, FGGY, MIR4711, AL035416.1, HOOK1, CYP2J2, RN7SL475P, C1orf87, PGBD4P8, LINC02778, LINC01748, AC099792.1, NFIA, NFIA-AS2, NFIA-AS1, AC099791.3, AC099791.4, AC099791.1, TM2D1, AC099791.2, PATJ, RNU6-414P, RNU6-1177P, LAMTOR5P1.
- chr1:65,003,470–67,398,724, 38 genes, copy number 7 (within-gene range 3–7): AL357078.2, RNU6-1176P, MIR3671, MIR101-1, AL357078.1, MRPS21P1, AK4, RPS29P7, DNAJC6, AL139294.1, COX6CP13, RNU2-15P, LEPROT, LEPR, AC119800.1, AC097063.1, AL513493.1, RN7SL854P, PDE4B, PDE4B-AS1, RNU4-88P, SGIP1, MIR3117, AL139147.1, TCTEX1D1, INSL5, DNAI4, AL592161.1, MIER1, SLC35D1, C1orf141, AL133320.1, AL133320.2, IL23R, RNU6-586P, RNU4ATAC4P, DNAJB6P4, IL12RB2.
- chr1:147,541,501–148,255,012, 25 genes, copy number 9: BCL9, AC242628.1, ACP6, RN7SL261P, AC241644.1, GJA5, AC241644.3, AC241644.2, AC239801.1, GJA8, GPR89B, PDZK1P1, AC239803.1, LINC02804, RNU1-129P, RNVU1-7, PDE4DIPP1, NBPF11, PFN1P4, ABHD17AP1, LINC02805, AC239809.3, RNA5SP57, AC239809.1, AC239809.2.
- chr1:149,583,865–153,704,385, 238 genes, copy number 8–14 (broad region; genes not listed).
- chr1:157,513,377–159,055,155, 55 genes, copy number 10: FCRL5, FCRL4, AL135929.2, AL135929.1, FCRL3, AL356276.1, AL356276.2, VDAC1P9, FCRL2, FCRL1, CD5L, MRPS21P2, AL139010.1, KIRREL1, KIRREL1-IT1, SMIM42, LINC01704, ELL2P1, CD1D, AL138899.2, AL138899.1, CD1A, HMGN1P5, CD1C, CD1B, CD1E, OR10T2, OR10K2, OR10T1P, EI24P2, OR10K1, OR10R2, AL365440.1, OR10R3P, OR10R1P, HSP90AA3P, OR6Y1, OR6P1, OR10X1, OR10Z1, SPTA1, OR6K1P, OR6K2, OR6K3, OR6K4P, OR6K5P, OR6N1, OR6K6, OR6N2, OR2AQ1P, OR10AA1P, MNDA, PYHIN5P, PYHIN1, IFI16.
- chr1:169,662,007–173,363,733, 80 genes, copy number 12 (within-gene range 5–12) (broad region; genes not listed).
- chr1:225,810,092–226,412,135, 24 genes, copy number 7: EPHX1, AL591895.1, TMEM63A, LEFTY1, AL117348.2, PYCR2, MIR6741, AL117348.1, LEFTY2, NDUFA3P3, SDE2, AL512343.2, H3-3A, LINC01703, AL512343.1, ACBD3, ACBD3-AS1, AL592045.1, MIXL1, LIN9, YBX1P9, AL359742.1, PARP1, AL359704.1.
- chr1:228,006,998–231,528,603, 123 genes, copy number 8–12 (within-gene range 5–12) (broad region; genes not listed).
- chr1:240,014,348–242,524,697, 48 genes, copy number 7 (within-gene range 5–7): FMN2, AL359918.1, Y_RNA, ADH5P3, AL359918.2, Y_RNA, AL590490.1, GREM2, AL358176.1, AL358176.2, AL358176.4, AL358176.3, RNU5F-8P, AL358176.5, Y_RNA, AL365184.2, AL365184.1, THAP12P8, RGS7, RFKP1, HNRNPA1P42, AL590682.1, MIR3123, AL592076.1, AL359764.1, AL359764.2, AL359764.3, FH, KMO, OPN3, CHML, AL133390.1, WDR64, AL365366.1, EXO1, RPL23AP20, BECN2, CFL1P4, MAP1LC3C, TUBB8P6, BX571673.1, PLD5, AL591686.2, RN7SKP12, AL591686.1, AL360271.2, RPL10AP5, AL360271.1.
- chr5:58,198–2,262,023, 79 genes, copy number 9–12 (broad region; genes not listed).
- chr5:9,363,275–11,904,446, 54 genes, copy number 8–23 (within-gene range 3–23): AC091906.1, AC027335.2, SEMA5A-AS1, AC027335.1, SNHG18, SNORD123, AC026787.1, TAS2R1, LINC02112, RNA5SP177, AC091838.1, LINC02221, AC091905.2, AC091905.3, AC091905.1, AC091905.4, AC034229.1, AC034229.6, AC034229.5, AC034229.2, AC034229.3, AC034229.4, ATPSCKMT, AC012640.1, CCT5, AC012640.4, AC012640.3, CMBL, Y_RNA, Y_RNA, AC012640.5, AC012640.2, MARCHF6, ROPN1L-AS1, ROPN1L, MIR6131, LINC01513, RPL30P7, AC092336.1, LINC02212, LINC02213, AC112200.2, AC112200.1, ANKRD33B, ANKRD33B-AS1, AC106760.1, AC106760.2, AC012629.4, AC012629.3, DAP, AC012629.2, AC012629.1, CTNND2, RNU6-429P.
- chr6:88,047,056–89,819,794, 32 genes, copy number 7–13 (within-gene range 5–13): AL136096.1, SPACA1, CNR1, AL121835.2, AL139042.1, AL121835.1, ACTBP8, AL139090.1, RNGTT, SNORA73, AL079342.3, AL079342.1, AL079342.2, RNU2-61P, AL353135.1, PNRC1, RN7SL336P, SRSF12, AL353135.2, PM20D2, GABRR1, GABRR2, TUBB3P1, UBE2J1, RRAGD, NACAP7, ANKRD6, RN7SL11P, AL159174.1, LYRM2, MDN1, AL096678.1.
- chr6:104,728,094–107,824,317, 50 genes, copy number 10–16 (within-gene range 2–16): HACE1, RNU6-897P, AL357315.1, AL357315.2, LIN28B-AS1, LIN28B, RNU6-1106P, BVES, BVES-AS1, POPDC3, PREP, AL133406.2, AL133406.1, RPL35P3, AL096794.1, LINC02836, Z97206.1, AL591518.1, RN7SKP211, PRDM1, ATG5, AL022067.1, U4, RN7SL47P, RNU6-344P, AL356859.1, CRYBG1, Y_RNA, RNA5SP211, AL109920.1, Y_RNA, RTN4IP1, RNU6-527P, QRSL1, RPL21P65, LINC02526, LINC02532, RNU6-117P, MIR587, CD24, MTRES1, BEND3, RNU6-1299P, PDSS2, AL591516.1, RPS24P12, SOBP, AL121957.1, AL096816.1, SCML4.
- chr6:110,562,175–111,483,715, 26 genes, copy number 12 (within-gene range 5–12): AL512430.3, AL512430.4, CDK19, AL512430.1, AL512430.2, AL603914.1, RNU6-957P, SNORA40C, RNU6-1115P, CNN2P9, Z84480.1, AMD1, AL357515.1, GTF3C6, RPF2, GSTM2P1, SLC16A10, RNU6-960P, AL360227.1, MFSD4B, AL080317.1, REV3L, AL080317.2, FCF1P5, REV3L-IT1, BRD7P4.
- chr6:123,216,339–126,203,817, 21 genes, copy number 9: TRDN, TRDN-AS1, AL445259.1, AL133257.1, NKAIN2, AL354936.1, RNF217-AS1, RNF217, TPD52L1, HDDC2, AL121938.1, AL450332.1, AL365259.1, LINC02523, HEY2, NCOA7, NCOA7-AS1, RN7SKP56, HINT3, RNA5SP216, TRMT11.
- chr6:132,271,982–132,763,459, 20 genes, copy number 7 (within-gene range 5–7): EEF1A1P36, MOXD1, STX7, RPL21P66, TAAR9, TAAR8, TAAR7P, TAAR6, TAAR5, TAAR4P, AL513524.1, TAAR3P, TAAR2, TAAR1, HLFP1, VNN1, CCNG1P1, VNN3, VNN2, AL032821.1.
- chr6:138,088,505–147,408,281, 123 genes, copy number 7–21 (broad region; genes not listed).
- chr6:148,155,120–152,637,801, 97 genes, copy number 9–18 (within-gene range 2–18) (broad region; genes not listed).
- chr10:78,943,328–86,403,201, 115 genes, copy number 12–31 (broad region; genes not listed).
- chr12:66,767–3,072,145, 77 genes, copy number 7–24 (broad region; genes not listed).
- chr12:64,264,762–65,491,430, 36 genes, copy number 10–29 (within-gene range 4–29): C12orf56, OOEPP2, ATP6V1E1P3, AC135279.1, XPOT, AC135279.2, AC135279.3, TBK1, AC136977.1, RASSF3, AC078962.2, SNORD83, AC078962.4, MIR548C, MIR548Z, AC078962.1, AC078962.3, AC025262.2, AC025262.1, GNS, TBC1D30, AC078815.1, AC025262.3, RPL7P39, LINC02389, LINC02231, RNU6ATAC42P, AC135895.1, WIF1, RNU6-166P, APOOP3, LEMD3, AC026124.2, MSRB3, AC026124.1, KRT18P60.
- chr12:66,302,493–69,823,204, 74 genes, copy number 19–51 (within-gene range 6–51) (broad region; genes not listed).
- chr12:71,582,293–72,670,758, 19 genes, copy number 18: AC078860.3, AC078860.2, ZFC3H1, AC078860.1, THAP2, AC073612.1, TMEM19, AC011601.1, RAB21, AC089984.1, AC089984.2, TBC1D15, MRS2P2, TPH2, AC090109.1, TRHDE, TRHDE-AS1, H3P35, CHCHD3P2.
- chr12:122,920,951–123,662,604, 34 genes, copy number 10 (within-gene range 6–10): ABCB9, OGFOD2, AC026362.1, ARL6IP4, PITPNM2, MIR4304, PITPNM2-AS1, AC026362.2, MPHOSPH9, AC073857.1, C12orf65, CDK2AP1, AC068768.1, RNA5SP375, SBNO1, Y_RNA, SBNO1-AS1, MIR8072, KMT5A, RILPL2, COPS5P2, SNRNP35, RILPL1, AC145423.1, AC145423.2, MIR3908, TMED2-DT, TMED2, DDX55, SNORA9B, EIF2B1, GTF2H3, AC117503.3, AC117503.2.
- chr14:46,651,010–49,374,383, 20 genes, copy number 7: RPL10L, MDGA2, AL359951.1, RPA2P1, RPL13AP2, RPS15AP3, MIR548Y, LINC00648, AL121576.1, AL359212.1, AL512358.1, AL512358.2, AL358335.3, RNU6-297P, AL358335.2, AL358335.1, RPL18P1, AL512360.1, AL110505.1, ATP5MC2P2.
- chr15:86,932,880–93,569,483, 178 genes, copy number 7–11 (within-gene range 6–11) (broad region; genes not listed).
- chr15:93,882,082–101,933,350, 171 genes, copy number 7–69 (within-gene range 7–92) (broad region; genes not listed).
- chr17:1,569,268–2,303,785, 35 genes, copy number 7 (within-gene range 3–7): SLC43A2, RN7SL105P, SCARF1, RILP, PRPF8, AC130343.3, TLCD2, MIR22HG, MIR22, WDR81, AC130343.1, SERPINF2, SERPINF1, SMYD4, RPA1, AC130689.1, RTN4RL1, AC099684.2, AC099684.1, AC099684.3, DPH1, AC090617.10, OVCA2, AC090617.3, AC090617.5, MIR132, MIR212, HIC1, SMG6, AC090617.9, AC090617.4, AC090617.6, AC090617.8, AC090617.7, MCUR1P1.
- chr17:4,807,152–5,248,182, 34 genes, copy number 7 (within-gene range 2–7): PLD2, MINK1, ATP6V0CP1, RN7SL784P, CHRNE, C17orf107, GP1BA, SLC25A11, RNF167, PFN1, ENO3, SPAG7, CAMTA2, AC004771.3, MIR6864, MIR6865, AC004771.1, AC004771.4, AC004771.2, INCA1, KIF1C, KIF1C-AS1, SLC52A1, AC012146.1, AC012146.2, ZFP3, ZNF232, ZNF232-AS1, USP6, AC012146.3, ZNF594, AC087500.1, SCIMP, AC087500.2.
- chr17:27,612,588–30,831,318, 193 genes, copy number 9 (broad region; genes not listed).
- chr17:61,354,763–78,925,387, 520 genes, copy number 7–44 (within-gene range 6–44) (broad region; genes not listed).
- chr17:79,730,943–83,095,122, 183 genes, copy number 7–9 (broad region; genes not listed).
- chr19:12,610,918–14,475,354, 108 genes, copy number 7 (broad region; genes not listed).
- chr20:34,688,688–35,950,370, 54 genes, copy number 19 (within-gene range 3–19): AL118520.1, NCOA6, TP53INP2, AL109824.1, HMGB3P1, GGT7, ACSS2, GSS, MYH7B, MIR499A, MIR499B, TRPC4AP, RNU6-407P, EDEM2, AL135844.1, PROCR, AL356652.1, RNA5SP483, MMP24OS, MT1P3, MMP24, AL121753.2, AL121753.1, EIF6, FAM83C-AS1, FAM83C, UQCC1, GDF5-AS1, GDF5, MIR1289-1, CEP250, CEP250-AS1, FO393401.1, C20orf173, ERGIC3, RPL36P4, FER1L4, RPL37P1, SPAG4, CPNE1, AL109827.1, RN7SKP271, RNU6-759P, RBM12, NFS1, ROMO1, RBM39, RPF2P1, U6, PHF20, COX7BP2, Y_RNA, HIGD1AP16, RNU4-40P.
- chr20:37,165,774–38,127,780, 22 genes, copy number 9 (within-gene range 4–9): AL031659.1, RPN2, GHRH, MANBAL, AL034422.1, SRC, RPL7AP14, BLCAP, NNAT, AL109614.1, PPIAP3, LINC01746, GLRXP1, LINC00489, AL162293.1, CTNNBL1, VSTM2L, RN7SKP185, TTI1, RPRD1B, RN7SL237P, AL031651.1.
- chr20:38,404,893–39,663,552, 35 genes, copy number 8–23: AL391095.1, AL391095.3, SNHG17, SNORA71, SNORA71B, SNORA71A, SNORA71C, SNORA71D, SNORA71, SNHG11, SNORA71E, SNORA60, RALGAPB, MIR548O2, RPS3P2, ADIG, ARHGAP40, AL035419.1, Metazoa_SRP, SLC32A1, ACTR5, RN7SKP173, PPP1R16B, RN7SL116P, FAM83D, AL023803.2, AL023803.1, DHX35, AL023803.3, NPM1P19, LINC01734, AL035251.1, ATG3P1, RN7SL680P, AL132981.1.
- chr20:44,841,925–45,976,075, 71 genes, copy number 9–17 (broad region; genes not listed).
- chr20:49,293,394–50,429,483, 29 genes, copy number 16–21 (within-gene range 5–21): KCNB1, AL035685.1, PTGIS, B4GALT5, RN7SL197P, SNRPFP1, RNU6-919P, SLC9A8, AL162615.1, SPATA2, Y_RNA, Metazoa_SRP, RNF114, KRT18P4, RNU6-147P, SNAI1, TRERNA1, UBE2V1, PEDS1-UBE2V1, PEDS1, LINC01275, AL161937.1, LINC01273, CEBPB-AS1, CEBPB, PELATON, LINC01270, LINC01271, RN7SL636P.
- chr20:58,634,772–61,083,750, 53 genes, copy number 7: LINC01711, STX16, STX16-NPEPL1, NPEPL1, AL139349.1, PIEZO1P2, AL132655.3, AL132655.2, MIR296, MIR298, GNAS-AS1, AL132655.1, GNAS, AL132655.7, AL132655.6, AL132655.4, AL132655.5, AL121917.1, AL121917.2, AL109840.2, AL109840.1, NELFCD, CTSZ, TUBB1, ATP5F1E, PRELID3B, MRPS16P2, ZNF831, EDN3, AL035250.1, AL035250.2, AL160410.1, PIEZO1P1, AL389889.2, AL389889.1, PHACTR3, PHACTR3-AS1, RNU7-141P, SYCP2, FAM217B, PPP1R3D, CDH26, C20orf197, AL132822.1, MIR646HG, MIR646, MTCO2P1, MIR4533, MIR548AG2, AL117372.1, AL139348.1, AL121910.1, LINC01718.

Autosomal genes at a single copy (total copy number 1): 0. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
